Surgical pathology report (de-identified scan), TCGA case TCGA-62-8402, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-8402-01A (Primary Tumor).

TSS Name: [REDACTED]

TSS Identifier: [REDACTED]

TSS Unique Patient #: [REDACTED]

Pathology Report-Summary:

Material:

Lung, right, upper lobe: 15.0 x 9.0 x 6.0 cm

Tumor: 2.5 x 2.5 x 1.5 cm

Diagnosis:

Adenocarcinoma, mixed subtype (partially: acinar, papillary, solid, BAC)

Infiltration of pleura visceralis

pT2, pN2 (8/28), pMx, G3

Supplementary examination:

EGFR mutation analysis (sanger sequencing, Ex 18 – 21)

EGFR mutation positive

p.E746_A750del (c.2235_49del)

[REDACTED]

[REDACTED]

Date:

Source: NCI Genomic Data Commons file 32b3cb52-f301-4555-aa37-3d7841c65e56 (TCGA-62-8402.C5EBD021-924A-48B4-A401-B7802F7ACF92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).